Somatic mutation profile of tumor specimen TCGA-ET-A39M-01A (aliquot TCGA-ET-A39M-01A-11D-A19J-08) from TCGA case TCGA-ET-A39M, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.1 years (12,441 days).
Specimen TCGA-ET-A39M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40fddb15-e2c8-47d7-a4c4-46c8a2562e4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39M-10A (Blood Derived Normal), aliquot TCGA-ET-A39M-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deea3512-3407-46d3-bff5-6d348b3c6128

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PNMA5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs782553555, COSV62625985; called by muse, mutect2, varscan2
- TMCO4 | c.1860C>T p.P620= | Silent (SNP) | VAF 54/229 reads (24%) | catalogued as rs765490684, COSV53876652; called by muse, mutect2, varscan2
- AC074085.2 | n.181G>T | RNA (SNP) | VAF 54/182 reads (30%) | called by muse, mutect2, varscan2
